Surgical pathology report (de-identified scan), TCGA case TCGA-EZ-7264, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site UNC, specimen TCGA-EZ-7264-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number : [REDACTED]

Diagnosis:

A, B: Brain, right frontal region, excision
- Oligodendroglioma, WHO grade II.

Comment:

Sections of the tumor were sent to the Cytogenetics Laboratory for 1p19q testing. The results of these tests will be reported separately by the Cytogenetics Laboratory.

[REDACTED] reviewed this case and concurs with the diagnosis.

Intraoperative Consult Diagnosis:

An intraoperative consultation was requested by [REDACTED] on [REDACTED] from [REDACTED] [REDACTED]

Smear A1: Right frontal tumor, biopsy

[REDACTED] w gr [REDACTED] oma
[REDACTED] at [REDACTED]

Frozen Section Pathologist: [REDACTED]

Clinical History:

[REDACTED]-year-old female with brain tumor.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "right frontal tumor." It holds multiple white/tan soft tissue fragments (1.2 x 1.2 x 0.3 cm in aggregate). A portion of the specimen is smeared for intraoperative consultation and the remainder is in block A1.

Container B is additionally labeled "right frontal tumor." It holds a 3.8 x 3.2 x 2.1 cm aggregate of fleshy white/tan soft tissue consistent with brain. Representative sections are submitted in blocks B1-B5 (approximately 80% of tissue is submitted).

[page 2 of 2]
Light Microscopy:

Light microscopic examination is performed by

The rapid intraoperative diagnosis is confirmed. Sections show an infiltrating low-grade glioma with prominent perinuclear halos, focal microcystic change, and delicate vasculature. Nuclei are relatively round and show only modest nuclear atypia. Mitotic figures are present but infrequent. The glioma infiltrates both gray and white matter.

Source: NCI Genomic Data Commons file 114eb8fc-abda-4871-be0c-e432fd02124b (TCGA-EZ-7264.1A18641E-75F5-4601-8D9B-4536805A9AEB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).